Somatic mutation profile of tumor specimen TCGA-RR-A6KA-01A (aliquot TCGA-RR-A6KA-01A-21D-A33T-08) from TCGA case TCGA-RR-A6KA, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 72.8 years (26,582 days).
Specimen TCGA-RR-A6KA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a8a256f-d96f-46a2-8b48-8619e1c0d7aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RR-A6KA-10A (Blood Derived Normal), aliquot TCGA-RR-A6KA-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81829065-6f06-4493-902a-8bd716d764b0

The open-access MAF lists 60 somatic variants for this specimen: 41 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 17, Nonsense Mutation 5, Frame Shift Del 1, Splice Site 1, Frame Shift Ins 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1637A>C p.Q546P | Missense Mutation (SNP) | VAF 15/37 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TACR3 | c.737+1G>A p.X246_splice | Splice Site (SNP) | VAF 20/55 reads (36%) | catalogued as rs760022956, CS104228, COSV59199949; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCG2 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as rs201034377, COSV52948355; called by muse, mutect2, varscan2
- ANO3 | c.178A>T p.T60S | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.001); catalogued as COSV99885276; called by muse, mutect2, varscan2
- ANPEP | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.683); catalogued as rs774552143, COSV100263462; called by muse, mutect2, varscan2
- APOH | c.776G>C p.S259T | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV99235943; called by muse, mutect2, varscan2
- ASXL1 | c.4445C>T p.A1482V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs779918659, COSV60126002; called by muse, mutect2, varscan2
- BMP2 | c.410G>C p.S137T | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV101122113; called by muse, mutect2, varscan2
- CD163L1 | c.2840T>A p.L947H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV100550605; called by muse, mutect2, varscan2
- CNKSR1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64163530; called by muse, mutect2, varscan2
- DCAF12L2 | c.137C>G p.A46G | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.199); catalogued as COSV100758804, COSV63580478; called by muse, mutect2, varscan2
- ETS1 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1314535450, COSV60094615; called by muse, mutect2, varscan2
- HECTD4 | c.5613G>A p.W1871* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV101108329; called by muse, mutect2, varscan2
- IL11RA | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201638429, COSV99426568; called by muse, mutect2, varscan2
- KSR2 | c.1522C>G p.H508D | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV100196526, COSV56664897, COSV56685444; called by muse, mutect2, varscan2
- LPAR2 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs557173160, COSV101345522; called by muse, mutect2, varscan2
- MAGEE2 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV64897535; called by muse, mutect2, varscan2
- MKI67 | c.5143G>A p.E1715K | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs746950894, COSV64077454; called by muse, mutect2, varscan2
- MROH5 | c.2182C>T p.Q728* | Nonsense Mutation (SNP) | VAF 13/62 reads (21%) | catalogued as rs778414997, COSV101436115; called by muse, mutect2, varscan2
- NELFA | c.1309C>G p.Q437E (on ENST00000542778; = p.Q426E on NM_005663.5) | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.36); catalogued as COSV100373824; called by muse, mutect2, varscan2
- OR2L2 | c.658G>T p.V220F | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV100824306; called by muse, mutect2, varscan2
- PANK4 | c.1372G>A p.G458R | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.756); catalogued as rs989407572, COSV101022543; called by muse, mutect2, varscan2
- PASD1 | c.1793G>A p.C598Y | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100949566; called by muse, mutect2, varscan2
- PKD1L1 | c.794C>A p.S265Y | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56974752, COSV99221182; called by muse, mutect2
- POLG2 | c.775C>T p.R259* | Nonsense Mutation (SNP) | VAF 3/33 reads (9%) | catalogued as rs782006396, COSV101604443; called by muse, mutect2
- PRAMEF5 | c.301C>G p.Q101E | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs1318738679; called by muse, mutect2, varscan2
- PSG6 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 83/458 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs778070572, COSV51829851; called by muse, mutect2, varscan2
- RNF144A | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1283151830, COSV57979905; called by muse, mutect2, varscan2
- TG | c.3878A>C p.Q1293P | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as rs1339865383, COSV99602880; called by muse, mutect2, varscan2
- TRIM44 | c.802A>G p.K268E | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as rs1413969656, COSV100195514; called by muse, mutect2, varscan2
- TRO | c.3556A>T p.S1186C | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99437168; called by muse, mutect2, varscan2
- TRPC6 | c.2164A>T p.M722L | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100723748; called by muse, mutect2, varscan2
- TSHZ3 | c.1581A>C p.E527D | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV99552540; called by muse, mutect2, varscan2
- TSR2 | c.25C>T p.R9* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV64318980; called by muse, mutect2, varscan2
- TTC7A | c.2383A>G p.K795E | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.192); catalogued as rs756085345, COSV99766906; called by muse, mutect2, varscan2
- TXN2 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.511); catalogued as COSV53397843; called by muse, mutect2, varscan2
- ZFHX3 | c.1796A>G p.N599S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV99214415; called by muse, mutect2, varscan2
- ZNF677 | c.1625A>G p.H542R | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as rs763662447, COSV100448140; called by muse, mutect2, varscan2
- ZNF804A | c.2615C>A p.T872K | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV56453476; called by muse, mutect2, varscan2
- MYOM3 | c.2215del p.H739Mfs*123 | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | called by mutect2, pindel, varscan2
- PCSK5 | c.1827dup p.P610Sfs*9 | Frame Shift Ins (INS) | VAF 17/85 reads (20%) | called by mutect2, pindel, varscan2
- ASPM | c.6573T>A p.T2191= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV99660992; called by muse, mutect2, varscan2
- CDC42BPG | c.4359C>T p.N1453= | Silent (SNP) | VAF 33/127 reads (26%) | catalogued as rs1565668533, COSV100712147; called by muse, mutect2, varscan2
- CEMIP2 | c.4107C>T p.R1369= | Silent (SNP) | VAF 25/109 reads (23%) | catalogued as COSV100987498; called by muse, mutect2, varscan2
- CIBAR1 | c.696T>C p.S232= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100844717; called by muse, mutect2, varscan2
- CSF1R | c.2007C>T p.G669= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs779661379, COSV99642896; called by muse, mutect2, varscan2
- HUWE1 | c.7272T>C p.S2424= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV99473986; called by muse, mutect2, varscan2
- KIF17 | c.120G>A p.Q40= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV99929645; called by muse, mutect2, varscan2
- MYO7A | c.3015G>A p.A1005= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs782375410, COSV101289256; called by muse, mutect2, varscan2
- NUP153 | c.3114C>T p.T1038= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV100020757; called by muse, mutect2, varscan2
- OR4D6 | c.609C>T p.N203= | Silent (SNP) | VAF 23/114 reads (20%) | catalogued as rs758028167, COSV55658915; called by muse, mutect2, varscan2
- OVOL2 | c.348G>A p.S116= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs769786984, COSV99602539, COSV99602588; called by muse, mutect2, varscan2
- PSCA | c.228G>A p.T76= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs1186571244, COSV100008309; called by muse, mutect2, varscan2
- PTPRT | c.1572G>A p.K524= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as rs6016756, COSV100630079; called by muse, mutect2
- SCTR | c.273A>G p.R91= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV99191713; called by muse, mutect2, varscan2
- SLC22A12 | c.636C>T p.G212= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as rs1272829728, COSV60572238; called by muse, mutect2, varscan2
- SLFNL1 | c.357C>T p.H119= | Silent (SNP) | VAF 5/89 reads (6%) | catalogued as COSV100263150; called by muse, mutect2
- TMEM131L | c.648G>A p.L216= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs763843224, COSV99548057, COSV99548445; called by muse, mutect2, varscan2
- C14orf177 | n.525C>A | RNA (SNP) | VAF 14/41 reads (34%) | catalogued as COSV100362736; called by muse, mutect2, varscan2
- SHMT1 | c.243-26C>T | Intron (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
